Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3370, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3370-01A (Primary Tumor).

[page 1 of 2]
☒ TEST: Surgical Pathology

Collected Date & Time: [REDACTED]

Result Name	Results	Units	Reference Range
☒ Surgical Pathology	COPY TO:		

COPY TO: [REDACTED]

Pre-Op Diagnosis

Gallstones, left renal mass

Post-Op Diagnosis

Same as above

Clinical History

Nothing indicated

Gross Description:

Two parts

Received in formalin labeled [REDACTED] 1 - "gallbladder" is a 6.8 x 3.1 x 1.8 cm intact gallbladder with a 0.2 cm cystic duct and an attached suture. The serosa is smooth and tan pink to purple. The mucosa is velvety and tan green. There are multiple round bosselated yellow choleliths ranging from 0.2 cm to 0.5 cm in greatest dimension and green bile in the lumen. The wall thickness averages 0.1 cm. The specimen is sectioned and representative sections are submitted in one cassette.

Received in formalin labeled [REDACTED] 2 - "left kidney" is a 265 gram nephrectomy specimen consisting of a 10.1 x 5.6 x 3.2 cm kidney with a moderate amount of attached perinephric fat. There is an attached 4.6 x 0.2 cm segment of ureter and a minimal amount of attached renal artery and renal vein at the hilum. There is a 4.3 x 2.5 x 1.4 cm red yellow mass in the lower pole. The mass appears focally above the inked deep margins. The remainder of the cut surface consists of tan brown parenchyma. The corticomedullary junction is well defined. The urothelium is glistening and white. No additional lesions are identified. No enlarged lymph nodes are identified. The adrenal gland is not present. The specimen is inked, serially sectioned and Representative sections are submitted as labeled: A - ureteral and renal artery margins; B - renal vein margin; C-E - mass to inked deep margin; F - mass to capsule; G - mass to capsule and uninvolved parenchyma; H and I - uninvolved parenchyma. Also received in the same container is a yellow green and blue cassettes labeled [REDACTED] for genomic research study.

Microscopic Description:

The slides labeled [REDACTED] are examined. See diagnosis.

Final Diagnosis

Gallbladder (cholecystectomy):

Chronic cholecystitis and cholelithiasis. PAS 6,2

Kidney, left (nephrectomy):

Tumor characteristics:

1. Histologic type: Conventional (clear cell) renal cell carcinoma
2. Tumor site: Lower pole
3. Size: 4.3 x 2.5 x 1.4 cm
4. Macroscopic extent of tumor: Tumor limited to kidney
5. Nuclear grade: Fuhrman grade 1-2/4
6. Lymphovascular space invasion: No unequivocal lymphovascular space invasion identified
7. Transcapsular invasion: No
8. Renal vein invasion: No
9. Vena caval invasion: Not resected
10. Adrenal gland: Not resected
- Surgical margin status:
1. Soft tissue margin: Negative
2. Ureteral margin: Negative
3. Vascular margin: Negative
- Lymph node status:
- No lymph nodes resected.
- Stage:
- pT1, Nx, Mx PAS 9 SPC-A

[page 2 of 2]
[REDACTED]

CPT: 88307, 88304

Comments

This test has been finalized at the [REDACTED] Campus.

#

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 9e9e8df6-e82e-4354-8b84-75c72c6c9ba2 (TCGA-A3-3370.491EE6AB-9C62-4A66-A04D-2BC767BA63F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).